Somatic mutation profile of tumor specimen TCGA-G9-6336-01A (aliquot TCGA-G9-6336-01A-11D-1786-08) from TCGA case TCGA-G9-6336, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.1 years (20,851 days).
Specimen TCGA-G9-6336-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9065f0c-8e36-4b7a-84b6-8133f5a54db2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6336-10A (Blood Derived Normal), aliquot TCGA-G9-6336-10A-01D-1786-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/712339ae-12e1-427d-967b-e5f42b3ea62c

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.2037A>T p.Q679H | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.976); catalogued as COSV57604880; called by muse, mutect2, varscan2
- COL17A1 | c.2981C>T p.P994L | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs763518143, COSV62227033, COSV62229351; called by muse, mutect2, varscan2
- DSN1 | c.194G>A p.C65Y | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV65519317; called by muse, mutect2
- HRNR | c.1798C>A p.H600N | Missense Mutation (SNP) | VAF 50/523 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.281); catalogued as rs200860192, COSV64258739; called by muse, mutect2, varscan2
- KIF11 | c.1433A>G p.E478G | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV53270943; called by muse, mutect2, varscan2
- KPRP | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs765434263, COSV64220950; called by muse, mutect2, varscan2
- MKLN1 | c.2170C>A p.P724T | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV61761062; called by muse, mutect2, varscan2
- NR6A1 | c.257G>A p.R86Q (on ENST00000487099 / NM_033334.4; = p.R82Q on NM_001489.5) | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60633705; called by muse, mutect2
- PAPPA2 | c.2890G>A p.D964N | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.709); catalogued as rs201513629, COSV62798363; called by muse, mutect2, varscan2
- RASEF | c.2192C>T p.S731L | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs767340817, COSV64587233; called by muse, mutect2, varscan2
- RASGRF1 | c.2840G>T p.R947L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV67249738, COSV67250135; called by muse, mutect2, varscan2
- RCBTB2 | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV60650306, COSV60650863; called by muse, mutect2, varscan2
- SUSD2 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100844277, COSV64204104; called by muse, mutect2, varscan2
- COL1A1 | c.1920C>T p.P640= | Silent (SNP) | VAF 20/206 reads (10%) | catalogued as rs745564892, COSV56803394; called by muse, mutect2, varscan2
- EDIL3 | c.888C>T p.L296= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV56895371; called by muse, mutect2, varscan2
- MKLN1 | c.2169T>G p.T723= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV61761055; called by muse, mutect2, varscan2
- PSMD7 | c.411G>A p.A137= | Silent (SNP) | VAF 13/142 reads (9%) | catalogued as rs766846835, COSV54697749; called by muse, mutect2
- PXDNL | c.3450C>A p.I1150= | Silent (SNP) | VAF 21/197 reads (11%) | catalogued as COSV62479427, COSV62488429; called by muse, mutect2, varscan2
